Gene-level copy-number profile of tumor specimen RC-B6SK-TMP1-A from RC case RC-B6SK, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.7 years (23,616 days).
Specimen RC-B6SK-TMP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 546a2492-0364-43f5-a80e-2fe31beaea40.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SK-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/2410e80b-3d0c-4db7-b338-e2bb6050870a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,199; copy number 2: 55,417; copy number 3: 194; copy number 4: 18; copy number 5: 23; copy number 6: 57.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,378,804, 22 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr14:22,197,446–22,513,998, 56 genes, copy number 6: AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.

Autosomal genes at a single copy (total copy number 1): 343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
